Gene-level copy-number profile of tumor specimen TCGA-29-1778-01A from TCGA case TCGA-29-1778, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 77.1 years (28,147 days).
Specimen TCGA-29-1778-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3ac1c2dd-76bc-4769-af18-b8e952e78513.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-29-1778-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8db10455-1ddd-47c5-afd4-829a39ef4b60

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,271; copy number 2: 3,216; copy number 3: 11,307; copy number 4: 18,942; copy number 5: 7,759; copy number 6: 9,603; copy number 7: 2,872; copy number 8: 1,286; copy number 9: 668; copy number 10: 937; copy number 11: 264; copy number 12: 586; copy number 13: 248; copy number 14: 153; copy number 15: 32; copy number 16: 76; copy number 17: 128; copy number 18: 1; copy number 19: 28; copy number 20: 105; copy number 21: 106; copy number 22: 122; copy number 23: 27; copy number 26: 30; copy number 28: 12; copy number 36: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-29-1778-01A-01D-0577-01): tumor purity 0.7, ploidy 4.67, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,559 genes in 38 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:6,264,269–10,181,239, 108 genes, copy number 10–17 (within-gene range 4–17) (broad region; genes not listed).
- chr1:36,795,527–37,034,515, 1 gene, copy number 18 (within-gene range 7–18): GRIK3.
- chr1:39,881,566–40,876,670, 43 genes, copy number 22: Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1, PPT1, OAZ1P1, RLF, RNU6-1237P, TMCO2, AL050341.2, ZMPSTE24, AL050341.1, COL9A2, AL031985.2, SMAP2, AL031985.1, AL031985.4, ZFP69B, AL031985.3, AL603839.4, ZFP69, AL603839.3, EXO5, AL603839.1, AL603839.2, ZNF684, AL356379.2, AL356379.1, GTF2F2P2, RIMS3, AL031289.2, AL031289.1, NFYC-AS1, NFYC, MIR30E, MIR30C1, KCNQ4, RN7SL326P, CITED4, AC119677.1.
- chr1:41,506,365–42,035,925, 1 gene, copy number 10 (within-gene range 4–10): HIVEP3.
- chr1:41,585,306–45,491,163, 136 genes, copy number 10–15 (within-gene range 4–15) (broad region; genes not listed).
- chr2:101,991,960–102,736,888, 16 genes, copy number 13: IL1R2, AC007271.1, IL1R1, IL1R1-AS1, IL1RL2, FAM183DP, IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9.
- chr2:106,093,308–106,194,301, 2 genes, copy number 14 (within-gene range 4–14): UXS1, AC018878.1.
- chr3:104,063,039–105,869,552, 4 genes, copy number 9: RAP1BP2, AC091804.1, ALCAM, CBLB.
- chr3:108,907,792–111,275,563, 28 genes, copy number 9 (within-gene range 6–9): GUCA1C, MORC1, U3, MORC1-AS1, C3orf85, AC063923.2, LINC00488, RNU6-1236P, AC063923.1, DPPA2, Metazoa_SRP, DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15, MIR4445, AC078980.1, DIMT1P1, NFYBP1, AC078918.1, AC117430.1, RNU6ATAC15P, RPSAP29, Y_RNA, NECTIN3-AS1, NECTIN3.
- chr3:112,696,908–117,997,592, 80 genes, copy number 11–26 (broad region; genes not listed).
- chr3:120,448,974–122,291,629, 35 genes, copy number 9 (within-gene range 6–9): AC126182.3, AC126182.1, AC126182.2, NDUFB4, HGD, RABL3, MTCO1P29, MTCO2P29, GTF2E1, NAP1L1P3, AC072026.2, LINC02049, AC072026.3, STXBP5L, AC072026.1, MIR5682, AC078857.1, AC079841.1, AC079841.2, POLQ, RPL7AP11, ARGFX, FBXO40, HCLS1, RN7SL172P, RNU4-62P, GOLGB1, IQCB1, EAF2, SLC15A2, ILDR1, Y_RNA, CD86, AC068630.1, CASR.
- chr4:68,447,463–69,813,888, 52 genes, copy number 22: TMPRSS11E, UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15, AC147055.1, AC093720.1, AC021146.8, UGT2B10, AC021146.9, AC021146.4, AC021146.11, AC021146.2, AC021146.3, AC021146.12, AC021146.6, AC021146.1, UGT2A3, AC021146.10, AC021146.5, AC021146.7, UGT2B27P, AC107401.1, UGT2B26P, UGT2B7, AC111000.2, AC111000.5, AC111000.3, AC111000.6, AC111000.1, AC111000.4, UGT2B11, AC114797.1, AC114786.1, UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P, AC108078.3, AC108078.2, UGT2B4, UGT2A3P7, AC093829.1, UGT2A2, UGT2A1, SULT1B1, SULT1D1P.
- chr4:71,741,696–73,258,798, 12 genes, copy number 10–17: GC, RNA5SP163, AC068721.1, NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2.
- chr4:73,263,960–73,264,084, 1 gene, copy number 17: AC053527.1.
- chr6:167,607–9,294,133, 181 genes, copy number 9–22 (within-gene range 6–22) (broad region; genes not listed).
- chr6:32,439,878–37,394,734, 194 genes, copy number 10 (broad region; genes not listed).
- chr6:41,683,978–44,307,506, 111 genes, copy number 9–20 (broad region; genes not listed).
- chr6:44,278,734–44,313,347, 2 genes, copy number 10: TCTE1, AARS2.
- chr7:62,275,361–64,266,931, 82 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr7:147,671,711–148,884,321, 19 genes, copy number 16 (within-gene range 5–16): AC005518.1, AC005518.2, RNU6-1184P, RNA5SP249, RN7SL456P, U3, RN7SL72P, AC083849.1, AC006974.1, AC006974.2, AC005229.2, AC005229.5, C7orf33, AC005229.1, AC005229.3, AC005229.4, CUL1, EZH2, RNU7-20P.
- chr10:4,051,726–13,423,133, 169 genes, copy number 10–13 (within-gene range 5–13) (broad region; genes not listed).
- chr10:16,276,871–23,393,467, 115 genes, copy number 9–26 (broad region; genes not listed).
- chr10:24,816,331–25,819,426, 18 genes, copy number 9–17: AL157385.2, PRTFDC1, AL157385.1, RN7SKP241, AL512598.2, AL512598.1, ENKUR, THNSL1, LINC01516, GPR158-AS1, GPR158, AL354976.1, RN7SKP220, GPN3P1, LINC00836, HIRAP1, RNA5SP306, RNU6-632P.
- chr10:31,602,862–33,600,040, 40 genes, copy number 20: AL161935.1, AL161935.3, AL161935.2, MACORIS, Y_RNA, ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1, RNU7-22P, PPIAP31, RPS24P13, AL158834.2, EPC1, AL158834.1, AL391839.2, AL391839.1, RNU6-1244P, AL391839.3, CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628.
- chr10:36,089,086–38,783,108, 58 genes, copy number 10: AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1.
- chr10:48,684,876–48,982,956, 1 gene, copy number 12 (within-gene range 6–12): WDFY4.
- chr10:48,835,541–49,115,522, 8 genes, copy number 12: AC035139.2, AC035139.1, AC060234.3, LRRC18, AC060234.2, AC060234.1, MIR4294, VSTM4.
- chr11:67,791,648–69,018,447, 40 genes, copy number 10 (within-gene range 4–10): FAM86C2P, ENPP7P7, AP003716.1, LINC02754, RNU6-46P, RPS3AP40, AC004923.1, AC004923.2, AC004923.3, OR7E1P, UNC93B1, ALDH3B1, AC004923.4, NDUFS8, MIR7113, MIR4691, TCIRG1, MIR6753, AP002807.1, CHKA, AP002992.1, KMT5B, C11orf24, AP002813.1, LRP5, PPP6R3, NDUFA3P2, AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1.
- chr11:69,083,176–69,083,258, 1 gene, copy number 10: MIR3164.
- chr11:74,493,851–88,176,593, 257 genes, copy number 9–36 (within-gene range 4–36) (broad region; genes not listed).
- chr15:32,284,152–33,194,714, 32 genes, copy number 12 (within-gene range 5–12): RNU6-18P, AC139426.1, AC139426.2, AC139426.4, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3, AC135983.2, LINC02256, AC123768.3, AC123768.2, GOLGA8N, RN7SL286P, AC123768.1, ARHGAP11A, AC123768.4, SCG5, SCG5-AS1, AC090877.2, GREM1, FMN1, AC090877.1, AC018515.1.
- chr17:68,867,289–70,135,608, 23 genes, copy number 11 (within-gene range 3–11): ABCA8, ABCA9-AS1, ABCA9, ABCA6, SEC24AP1, MIR4524B, MIR4524A, ABCA10, PRO1804, AC005495.1, ABCA5, SNRPGP4, AC115085.1, MAP2K6, AC015920.1, AC002546.1, LINC01483, AC002545.1, LINC01497, Y_RNA, AC005208.1, LINC01028, KCNJ16.
- chr18:41,341,319–47,176,364, 72 genes, copy number 13–16 (broad region; genes not listed).
- chr19:9,621,249–20,571,095, 627 genes, copy number 12–21 (within-gene range 7–21) (broad region; genes not listed).
- chr19:38,867,830–39,846,379, 66 genes, copy number 14 (broad region; genes not listed).
- chr21:10,328,411–46,665,124, 745 genes, copy number 9–11 (broad region; genes not listed).
- chr22:27,748,277–32,361,161, 177 genes, copy number 9–13 (within-gene range 8–13) (broad region; genes not listed).
- chr22:32,362,972–32,368,567, 2 genes, copy number 13: AL021937.6, AL021937.5.

Autosomal genes at a single copy (total copy number 1): 379. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
